Somatic mutation profile of tumor specimen ALCH-B0CP-TTP1-A (aliquot ALCH-B0CP-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0CP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.6 years (23,581 days).
Specimen ALCH-B0CP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4796043a-a553-4137-ace7-e2b6ffa6575a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CP-NB1-A (Blood Derived Normal), aliquot ALCH-B0CP-NB1-A-2-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a3107c5-4286-47b5-b9d6-6e4255ec6bb8

The open-access MAF lists 374 somatic variants for this specimen: 237 protein-altering or splice-affecting, 86 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 206, Silent 86, Intron 22, Nonsense Mutation 17, RNA 12, Splice Site 8, 5'UTR 8, 3'UTR 5, Frame Shift Del 4, 5'Flank 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BEST1 | c.102C>T p.G34= | Silent (SNP) | VAF 28/277 reads (10%) | catalogued as rs771898125, CS109045; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 691/836 reads (83%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>C p.G245R | Missense Mutation (SNP) | VAF 74/166 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 82/170 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, varscan2
- ADAM29 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661589; called by muse, mutect2, varscan2
- ADAMTS10 | c.2047G>A p.D683N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782184728; called by muse, mutect2, varscan2
- ADCY2 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as rs1168542317, COSV57861690, COSV57864042; called by muse, mutect2, varscan2
- ADGRG4 | c.4452G>T p.R1484S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV54950406; called by muse, mutect2, varscan2
- ADGRG4 | c.7287C>A p.S2429R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV99795206; called by muse, mutect2, varscan2
- AK9 | c.3103G>T p.E1035* | Nonsense Mutation (SNP) | VAF 19/187 reads (10%) | catalogued as COSV58143013; called by muse, mutect2, varscan2
- ALOX12 | c.1689G>T p.M563I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.309); catalogued as COSV52349599; called by muse, mutect2, varscan2
- AMDHD1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141656136, COSV99900521; called by muse, mutect2, varscan2
- ATAD3B | c.758C>T p.T253M (on ENST00000308647; = p.T359M on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs752026914; called by muse, mutect2, varscan2
- ATG2A | c.3532C>T p.R1178* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as rs375724306; called by muse, mutect2, varscan2
- AXIN2 | c.1628G>T p.C543F | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.97); catalogued as rs749312775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BIN1 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs747660857; ClinVar: uncertain significance; called by muse, varscan2
- CAPN13 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1469906412; called by muse, mutect2, varscan2
- CARD11 | c.1053C>G p.C351W | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); catalogued as COSV101210731; called by muse, mutect2, varscan2
- CARMIL1 | c.2903C>T p.S968L | Missense Mutation (SNP) | VAF 143/316 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.436); catalogued as rs1228442164; called by muse, mutect2, varscan2
- CCDC27 | c.1322-2A>G p.X441_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | catalogued as rs747879993; called by muse, mutect2, varscan2
- CDH12 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561233951; called by muse, varscan2
- CLIP2 | c.2065C>A p.L689M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1383889994; called by muse, mutect2, varscan2
- CNBD2 | c.1656del p.K553Nfs*6 (on ENST00000373973 / NM_001365709.1; = p.K549Nfs*6 on NM_080834.4) | Frame Shift Del (DEL) | VAF 45/189 reads (24%) | catalogued as COSV62586441; called by mutect2, pindel, varscan2
- CNTN6 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs1485711247; called by muse, mutect2, varscan2
- CORIN | c.1843+2T>C p.X615_splice | Splice Site (SNP) | VAF 67/170 reads (39%) | catalogued as rs1201628634; called by muse, mutect2, varscan2
- DGKG | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 41/340 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs370992136; called by muse, mutect2, varscan2
- DOCK2 | c.1412A>G p.K471R | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV56965751; called by muse, mutect2, varscan2
- DYNC1H1 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs369033191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1H1 | c.6049A>T p.T2017S | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64137647; called by muse, mutect2, varscan2
- EMC8 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs768068437; called by muse, mutect2, varscan2
- ENOX1 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1424225426; called by muse, varscan2
- ETNK2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs754108955; called by muse, mutect2, varscan2
- EVC | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767972554; called by muse, mutect2, varscan2
- FAM124A | c.983C>A p.P328Q (on ENST00000322475 / NM_001242312.2; = p.P364Q on NM_145019.4) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.619); catalogued as COSV54476404; called by muse, mutect2, varscan2
- FBXO7 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 76/492 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV56676857, COSV56676902; called by muse, varscan2
- FSTL5 | c.2108G>T p.G703V | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051479; called by muse, mutect2, varscan2
- FUT1 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1307121964; called by muse, mutect2, varscan2
- GPATCH2 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 53/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs537051072; called by muse, mutect2, varscan2
- GRID1 | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60037614; called by muse, mutect2, varscan2
- HHIPL1 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs762581942; called by muse, mutect2, varscan2
- HTR7 | c.1295+1G>T p.X432_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV53285166; called by muse, mutect2, varscan2
- IGKV1D-43 | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 187/428 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs751378035; called by muse, mutect2, varscan2
- INTS5 | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 78/119 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1431658805; called by muse, mutect2, varscan2
- IRX6 | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762774997; called by muse, varscan2
- KCNG2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769581960, COSV60267267; called by mutect2, varscan2
- KIAA0930 | c.1144G>A p.V382I (on ENST00000336156 / NM_001009880.2; = p.V387I on NM_015264.2) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs759747238, COSV99325791; called by muse, mutect2, varscan2
- KRBA1 | c.1487G>A p.G496E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55442410; called by muse, varscan2
- LRCH4 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs200374154, COSV59643033; called by muse, mutect2, varscan2
- LRRC74A | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs1256712072; called by muse, mutect2, varscan2
- MID2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99464652; called by muse, mutect2, varscan2
- MYH4 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV55119236; called by muse, mutect2, varscan2
- MYOM1 | c.4814C>T p.S1605L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs373194302; called by muse, mutect2, varscan2
- NAA15 | c.2282C>A p.S761* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as CM135250, COSV56721135; called by muse, mutect2, varscan2
- NAV3 | c.4518C>A p.D1506E | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs745708359; called by muse, mutect2, varscan2
- NCKAP5 | c.1660G>T p.V554L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1396074467; called by muse, varscan2
- NKAIN3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755745818; called by muse, mutect2, varscan2
- NPL | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 156/512 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs149443533, CM109831; called by muse, varscan2
- NTRK2 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs778391314, COSV52890631; called by muse, mutect2, varscan2
- OR4C15 | c.767G>T p.S256I (on ENST00000314644; = p.S202I on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/316 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV58952464, COSV58953494; called by muse, mutect2
- OTOF | c.3157G>A p.A1053T (on ENST00000272371 / NM_194248.3; = p.A306T on NM_004802.4) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs148852653; called by muse, mutect2, varscan2
- OXCT1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 40/719 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs772982372; called by muse, mutect2
- PAMR1 | c.1039C>T p.R347* (on ENST00000619888 / NM_001001991.3; = p.R364* on NM_015430.4) | Nonsense Mutation (SNP) | VAF 103/261 reads (39%) | catalogued as rs774065416, COSV99552688; called by muse, mutect2, varscan2
- PDGFRA | c.2812G>T p.E938* | Nonsense Mutation (SNP) | VAF 81/706 reads (11%) | catalogued as COSV57267936, COSV57270358; called by muse, mutect2, varscan2
- PDIA4 | c.1201C>T p.R401C (on ENST00000286091 / NM_001371244.1; = p.R400C on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs749840067; called by muse, mutect2, varscan2
- PDZD8 | c.2935G>A p.G979S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs770960594; called by muse, mutect2, varscan2
- PIK3C2G | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.051); catalogued as COSV56834643; called by muse, mutect2, varscan2
- PLEKHF1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371888855; called by muse, mutect2, varscan2
- POU3F4 | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV64537717, COSV64539013; called by muse, mutect2, varscan2
- PTGDS | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as rs1358649692; called by muse, mutect2, varscan2
- REV1 | c.3584C>A p.T1195N | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1178371887; called by muse, varscan2
- RFC3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761845498, COSV66296589; called by muse, mutect2, varscan2
- SCN2A | c.4477G>T p.E1493* | Nonsense Mutation (SNP) | VAF 32/252 reads (13%) | catalogued as rs1553462211; called by muse, varscan2
- SEPTIN6 | c.701C>G p.P234R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59715333; called by muse, mutect2, varscan2
- SH3RF2 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs745427899; called by muse, mutect2, varscan2
- SLC22A15 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as rs767277983; called by muse, mutect2, varscan2
- SLC47A2 | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs780099375; called by muse, mutect2, varscan2
- SLC7A14 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757402409, COSV99200721; called by muse, mutect2
- SMPD1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299600137, COSV100192495, COSV54966742; called by muse, mutect2, varscan2
- SPATA13 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs531638025, COSV57976855; called by muse, mutect2, varscan2
- SPATA31D1 | c.2699A>T p.Q900L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV61201135; called by muse, mutect2, varscan2
- SPTBN5 | c.9250C>T p.R3084W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs559715695, COSV100312101; called by muse, mutect2, varscan2
- TBCD | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201046462; called by muse, mutect2, varscan2
- TBX20 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs113201899, COSV68786032; called by muse, mutect2, varscan2
- TLN1 | c.6017G>T p.R2006L | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs759087292, COSV59208981; called by muse, mutect2, varscan2
- TRAM1L1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1459978922, COSV60292336; called by muse, varscan2
- TRAV14DV4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284306379; called by muse, mutect2, varscan2
- TTC26 | c.469T>G p.L157V | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1240902626; called by muse, mutect2, varscan2
- VPS33A | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0.009); catalogued as COSV57357171; called by muse, mutect2, varscan2
- VPS36 | c.910C>G p.R304G | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100955250; called by muse, mutect2, varscan2
- WBP11 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.98); catalogued as COSV53765029; called by muse, mutect2, varscan2
- WNK3 | c.1482_1483del p.K497Efs*40 | Frame Shift Del (DEL) | VAF 49/120 reads (41%) | catalogued as rs1569538191; called by mutect2, pindel, varscan2
- YWHAE | c.639C>G p.S213R | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.564); catalogued as rs776960456; called by muse, mutect2, varscan2
- ZBTB10 | c.1043A>G p.Y348C | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs765861770; called by muse, mutect2
- ZKSCAN8 | c.1054T>C p.C352R | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640010; called by muse, mutect2, varscan2
- ZNF366 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1248958132, COSV100574250; called by mutect2, varscan2
- ZNF568 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 13/93 reads (14%) | catalogued as COSV61740936; called by muse, mutect2, varscan2
- ZNF600 | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100593012; called by muse, mutect2, varscan2
- ZSCAN16 | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV61258693; called by muse, mutect2, varscan2
- ACADSB | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS3 | c.3225C>G p.N1075K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRG4 | c.3167C>A p.S1056* | Nonsense Mutation (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- AGAP3 | c.1912A>T p.N638Y (on ENST00000622464; = p.N674Y on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD36B | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- APEX2 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ARAP1 | c.2575G>T p.A859S (on ENST00000393609 / NM_001040118.2; = p.A614S on NM_015242.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARFGEF1 | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 89/250 reads (36%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF12 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ASMT | c.39T>G p.N13K | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATAD5 | c.2984A>T p.E995V | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ATP10B | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- BEND3 | c.1698C>A p.S566R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- BMP5 | c.376C>G p.R126G | Missense Mutation (SNP) | VAF 142/349 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- BOP1 | c.1425-2A>G p.X475_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- BPIFB2 | c.1259-1G>C p.X420_splice | Splice Site (SNP) | VAF 47/281 reads (17%) | called by muse, mutect2, varscan2
- BRDT | c.2242C>A p.Q748K | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- C20orf194 | c.1310+2T>C p.X437_splice | Splice Site (SNP) | VAF 33/482 reads (7%) | called by muse, mutect2
- C7 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CAMTA2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPRIN1 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CASP10 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CBY2 | c.103A>T p.R35* | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- CCRL2 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CD27 | c.168T>G p.H56Q | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDA | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH20 | c.2212T>G p.W738G | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDRT1 | c.1073A>T p.D358V | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, varscan2
- CEP126 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CLASP2 | c.3844G>T p.A1282S (on ENST00000359576; = p.A1281S on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CLMP | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN3 | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- COL12A1 | c.1948A>T p.T650S | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, varscan2
- CPEB3 | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRB1 | c.2792G>T p.S931I | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- DCAF1 | c.2924T>C p.L975S | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DCAF8L1 | c.1643T>A p.L548H | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DEFB114 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- DENND4B | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKG | c.834C>A p.H278Q | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- DIAPH3 | c.2011_2012del p.N671* (on ENST00000400324 / NM_001042517.2; = p.N408* on NM_030932.3) | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel, varscan2
- EOMES | c.110C>G p.P37R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPB41 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated, low confidence (0.89); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- EPS8L3 | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ESRP1 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2
- F13B | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- FAM222B | c.1103_1108del p.H368_Q369del | In Frame Del (DEL) | VAF 7/55 reads (13%) | called by pindel, varscan2
- FMN2 | c.5156G>T p.S1719I | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- FMNL1 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- FXYD5 | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GALNT13 | c.1031T>A p.V344D | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPAT2 | c.1957T>C p.W653R | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPR63 | c.387G>C p.L129F | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GPRC5C | c.1187C>A p.A396D (on ENST00000652232; = p.A351D on NM_018653.4) | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- GUCY2D | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HM13 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- HMCES | c.257A>T p.D86V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- HSPG2 | c.4406G>T p.R1469L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGLV3-9 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 162/320 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IQCA1 | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ITGB6 | c.1799G>T p.G600V | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IVL | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- JAG2 | c.2737C>A p.L913M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KCNA5 | c.1174C>A p.Q392K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- KCNH6 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNJ3 | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIAA0753 | c.2883A>T p.E961D | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF18B | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KPNA4 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, varscan2
- KRTAP12-4 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LAMA1 | c.8023C>A p.L2675M | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.3454C>G p.L1152V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LARGE1 | c.1106G>A p.C369Y | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRIQ1 | c.277A>C p.M93L | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRRTM3 | c.604G>C p.A202P | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- LTBP4 | c.221G>C p.R74P (on ENST00000308370 / NM_001042544.1; = p.R37P on NM_003573.2) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LUC7L | c.603C>G p.D201E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MDGA1 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MTOR | c.4028T>C p.L1343S | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MTUS2 | c.2263G>T p.V755F | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUCL3 | c.1125C>A p.D375E (on ENST00000304311; = p.D1251E on NM_080870.4) | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); called by mutect2, varscan2
- MYH1 | c.1748T>C p.I583T | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MYH13 | c.940T>A p.F314I | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MYH8 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MYH9 | c.5689C>T p.Q1897* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- MYO5C | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MYRFL | c.194C>G p.P65R | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- NDUFAF6 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- NECTIN2 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- NHSL2 | c.661G>A p.E221K (on ENST00000510661; = p.E587K on NM_001013627.2) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NOTO | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NPHP4 | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- NUPR2 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.202); called by muse, mutect2
- OR10K2 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, mutect2
- OR51A4 | c.881G>C p.C294S | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- OR6M1 | c.756C>G p.N252K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PAPPA2 | c.4048G>T p.V1350F | Missense Mutation (SNP) | VAF 225/591 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- PCDH12 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHAC1 | c.2434-2A>G p.X812_splice | Splice Site (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3101G>T p.R1034L | Missense Mutation (SNP) | VAF 67/393 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- POLA2 | c.871C>A p.L291I | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- POTEM | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 68/652 reads (10%) | called by muse, varscan2
- PPP1R7 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PPP2R3A | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 38/210 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PPP2R5C | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 36/203 reads (18%) | called by muse, mutect2, varscan2
- PRAMEF5 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROM1 | c.522_523insATAGAGA p.Y175Ifs*24 | Frame Shift Ins (INS) | VAF 5/205 reads (2%) | called by muse*, mutect2, varscan2*
- PRRC2B | c.3850C>T p.Q1284* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- PRSS36 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PUS7 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD18 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP2 | c.3286C>T p.R1096* | Nonsense Mutation (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- RANBP2 | c.9546G>T p.L3182F | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCOR1 | c.468del p.E158Kfs*69 | Frame Shift Del (DEL) | VAF 25/137 reads (18%) | called by mutect2, pindel, varscan2
- RELCH | c.2263T>A p.L755M | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, varscan2
- RRP15 | c.481A>T p.N161Y | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RYR2 | c.2591C>A p.P864H | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SCN4A | c.1349A>T p.Y450F | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SENP7 | c.2389C>T p.L797F | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SGCZ | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
- SLCO4C1 | c.1620+2T>A p.X540_splice | Splice Site (SNP) | VAF 35/198 reads (18%) | called by muse, mutect2, varscan2
- SLITRK3 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMNDC1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SPATA5 | c.2018C>T p.S673F | Missense Mutation (SNP) | VAF 48/280 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ST8SIA6 | c.1057A>T p.I353L | Missense Mutation (SNP) | VAF 86/357 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK25 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SULF1 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- TBC1D5 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.094); called by muse, varscan2
- TMEM200A | c.1166A>G p.H389R | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- TNRC6A | c.5119T>C p.S1707P | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TTN | c.78068T>C p.V26023A (on ENST00000591111; = p.V18599A on NM_003319.4) | Missense Mutation (SNP) | VAF 39/323 reads (12%) | PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- UGT2A1 | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC13C | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP21 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- VEPH1 | c.120G>T p.K40N | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- WDR36 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 63/351 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZBTB2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZEB1 | c.3041G>T p.R1014M | Missense Mutation (SNP) | VAF 72/298 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, varscan2
- ZNF404 | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ZNF536 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ADAMTS5 | c.1977C>T p.V659= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as rs776991293; called by muse, mutect2, varscan2
- ALX4 | c.1068C>A p.G356= | Silent (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- APBA1 | c.777G>A p.P259= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- APOB | c.6030T>C p.T2010= | Silent (SNP) | VAF 59/233 reads (25%) | called by muse, mutect2, varscan2
- ASTN1 | c.3561C>A p.T1187= | Silent (SNP) | VAF 75/304 reads (25%) | catalogued as COSV62500884; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1329G>T p.L443= | Silent (SNP) | VAF 125/348 reads (36%) | called by muse, mutect2, varscan2
- BEND4 | c.771G>A p.L257= | Silent (SNP) | VAF 58/209 reads (28%) | called by muse, varscan2
- BRINP3 | c.2202G>T p.L734= | Silent (SNP) | VAF 31/190 reads (16%) | called by muse, mutect2, varscan2
- C15orf62 | c.96G>A p.V32= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- C16orf71 | c.423G>A p.E141= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1337165011; called by muse, mutect2, varscan2
- CAMKK2 | c.1761C>T p.P587= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs760249050; called by muse, mutect2, varscan2
- CCDC141 | c.1329C>T p.T443= | Silent (SNP) | VAF 37/333 reads (11%) | catalogued as rs1028888938; called by muse, mutect2, varscan2
- CCDC88A | c.4428G>T p.P1476= (on ENST00000436346 / NM_001365480.1; = p.P1475= on NM_001135597.2) | Silent (SNP) | VAF 110/406 reads (27%) | catalogued as COSV99710870; called by muse, varscan2
- CD207 | c.399C>A p.A133= | Silent (SNP) | VAF 80/275 reads (29%) | called by muse, mutect2, varscan2
- CLIP4 | c.1443C>T p.C481= | Silent (SNP) | VAF 79/553 reads (14%) | catalogued as rs140728187; called by muse, mutect2, varscan2
- CLTA | c.453C>T p.D151= | Silent (SNP) | VAF 24/232 reads (10%) | catalogued as rs758949311, COSV99643543; called by muse, mutect2, varscan2
- CR1 | c.5640C>A p.G1880= | Silent (SNP) | VAF 20/197 reads (10%) | called by muse, mutect2, varscan2
- CRIP2 | c.498G>A p.A166= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- CUL7 | c.2886G>A p.R962= | Silent (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- CYFIP2 | c.2508C>A p.L836= (on ENST00000616178 / NM_001291722.2; = p.L811= on NM_014376.4) | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2772G>T p.S924= (on ENST00000400246; = p.S993= on NM_014662.5) | Silent (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- DGKG | c.231G>T p.L77= | Silent (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- DLGAP1 | c.381C>A p.A127= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1283109626; called by muse, mutect2, varscan2
- DSE | c.78C>T p.D26= | Silent (SNP) | VAF 42/342 reads (12%) | catalogued as rs146524076, COSV59065554; called by muse, mutect2, varscan2
- ERBB4 | c.1630C>A p.R544= | Silent (SNP) | VAF 85/440 reads (19%) | catalogued as COSV53516478; called by muse, mutect2, varscan2
- ESR1 | c.1485G>C p.L495= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- EVPL | c.3327G>A p.A1109= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1287454564, COSV56906903; called by muse, mutect2, varscan2
- F8 | c.1845C>A p.P615= | Silent (SNP) | VAF 58/171 reads (34%) | catalogued as CD080838, COSV64269367; called by muse, mutect2, varscan2
- FBF1 | c.117G>A p.A39= (on ENST00000586717; = p.A53= on NM_001319193.1) | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs767135992, COSV100045706, COSV59866914; called by muse, mutect2, varscan2
- FBN1 | c.7605C>T p.C2535= | Silent (SNP) | VAF 71/273 reads (26%) | catalogued as rs113544411, CM000515, CM054714, COSV57321873; called by muse, mutect2, varscan2
- FBN2 | c.7740G>A p.S2580= | Silent (SNP) | VAF 85/383 reads (22%) | catalogued as rs942206547; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF15 | c.789C>G p.R263= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- GPR108 | c.762G>A p.S254= (on ENST00000264080 / NM_001080452.1; = p.S12= on NM_020171.2) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs768815542, COSV51184326; called by muse, mutect2, varscan2
- GRIN2C | c.87C>A p.G29= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- GRM5 | c.1806C>A p.I602= | Silent (SNP) | VAF 99/273 reads (36%) | called by muse, mutect2, varscan2
- HDC | c.1032C>T p.T344= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs1567450060, COSV51069229; called by muse, mutect2, varscan2
- IMPA2 | c.207G>A p.L69= | Silent (SNP) | VAF 34/177 reads (19%) | called by muse, mutect2, varscan2
- ITGA4 | c.2139T>C p.I713= | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
- LRRC7 | c.3747T>C p.G1249= (on ENST00000651989 / NM_001370785.2; = p.G1216= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- MPHOSPH9 | c.666A>T p.I222= | Silent (SNP) | VAF 41/237 reads (17%) | called by muse, mutect2, varscan2
- MROH2B | c.2424C>T p.I808= | Silent (SNP) | VAF 55/300 reads (18%) | catalogued as rs546133595, COSV68188144; called by muse, mutect2, varscan2
- MTR | c.1491C>G p.V497= | Silent (SNP) | VAF 82/493 reads (17%) | called by muse, mutect2, varscan2
- MYCT1 | c.120C>A p.L40= | Silent (SNP) | VAF 21/137 reads (15%) | called by muse, mutect2, varscan2
- NAE1 | c.564A>G p.P188= | Silent (SNP) | VAF 50/161 reads (31%) | called by muse, mutect2, varscan2
- NAGA | c.870C>T p.S290= | Silent (SNP) | VAF 125/239 reads (52%) | catalogued as rs144984228; called by muse, mutect2, varscan2
- NUP205 | c.4083A>T p.G1361= | Silent (SNP) | VAF 133/420 reads (32%) | catalogued as rs764275655; called by muse, mutect2, varscan2
- OR10D3 | c.12G>A p.K4= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, varscan2
- OR1S1 | c.387G>T p.G129= | Silent (SNP) | VAF 40/298 reads (13%) | catalogued as rs1309739250; called by muse, mutect2, varscan2
- OR2T2 | c.324G>T p.L108= | Silent (SNP) | VAF 50/580 reads (9%) | catalogued as COSV61619372; called by muse, mutect2
- OR4C13 | c.399C>A p.V133= | Silent (SNP) | VAF 87/120 reads (73%) | called by muse, mutect2, varscan2
- OR6A2 | c.579A>T p.S193= | Silent (SNP) | VAF 97/285 reads (34%) | catalogued as rs148808514; called by muse, mutect2, varscan2
- OR9A2 | c.786G>A p.Q262= | Silent (SNP) | VAF 56/164 reads (34%) | called by muse, mutect2, varscan2
- PCDHGB7 | c.162A>G p.L54= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs748774040, COSV99531107; called by muse, mutect2, varscan2
- PDZRN4 | c.2658G>A p.K886= (on ENST00000402685 / NM_001164595.2; = p.K628= on NM_013377.4) | Silent (SNP) | VAF 41/267 reads (15%) | catalogued as rs1383519759, COSV54216700; called by muse, mutect2, varscan2
- PKHD1L1 | c.11958G>A p.K3986= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as rs369362762; called by muse, mutect2, varscan2
- PLCB1 | c.1707C>A p.S569= | Silent (SNP) | VAF 175/304 reads (58%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.1182T>C p.H394= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.1116C>G p.P372= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- PPAT | c.1437A>G p.K479= | Silent (SNP) | VAF 20/251 reads (8%) | catalogued as rs1251994805, COSV99947254; called by muse, mutect2
- PPP1R37 | c.1821C>T p.A607= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs779404720, COSV55527099; called by muse, mutect2, varscan2
- PTPRH | c.2685C>T p.P895= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV54749509; called by muse, mutect2, varscan2
- PXYLP1 | c.918C>T p.V306= | Silent (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- RTN4R | c.825G>T p.L275= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- SGCZ | c.579G>T p.V193= | Silent (SNP) | VAF 77/159 reads (48%) | called by muse, mutect2, varscan2
- SHC1 | c.354C>T p.G118= (on ENST00000368445 / NM_183001.5; = p.G8= on NM_003029.5) | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs762798440; called by muse, mutect2, varscan2
- SLC16A7 | c.951C>T p.F317= | Silent (SNP) | VAF 41/276 reads (15%) | catalogued as rs1490683240; called by muse, mutect2, varscan2
- SLC8A1 | c.72T>C p.S24= | Silent (SNP) | VAF 102/245 reads (42%) | catalogued as rs751105395; called by muse, varscan2
- SOX5 | c.981C>G p.A327= | Silent (SNP) | VAF 72/333 reads (22%) | catalogued as rs142710312; called by muse, mutect2, varscan2
- TAS2R5 | c.832A>C p.R278= | Silent (SNP) | VAF 67/162 reads (41%) | catalogued as COSV56094749; called by muse, mutect2, varscan2
- TCEAL4 | c.147G>A p.R49= | Silent (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- TGM6 | c.1191C>A p.A397= | Silent (SNP) | VAF 48/556 reads (9%) | catalogued as rs147554438; called by muse, mutect2
- TMED9 | c.621C>T p.S207= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV50353962; called by muse, mutect2, varscan2
- TNIK | c.1695C>T p.P565= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- TP53 | c.732C>G p.G244= | Silent (SNP) | VAF 78/166 reads (47%) | catalogued as COSV52677306, COSV52755988, COSV52773862, COSV53128429; called by muse, varscan2
- TRIM71 | c.1869C>T p.A623= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs763025137; called by muse, mutect2, varscan2
- TUBA3C | c.999C>A p.A333= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- UBE3B | c.1599T>C p.C533= | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- ULK2 | c.1083G>A p.S361= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs761045130; called by muse, mutect2
- VASH2 | c.222C>T p.H74= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- WDR87 | c.2095C>A p.R699= | Silent (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- WHRN | c.954C>T p.S318= | Silent (SNP) | VAF 44/226 reads (19%) | catalogued as rs779467474; called by muse, mutect2, varscan2
- ZFHX2 | c.3897G>A p.E1299= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs777039436; called by muse, varscan2
- ZNF292 | c.1044C>T p.T348= | Silent (SNP) | VAF 7/37 reads (19%) | called by mutect2, varscan2
- ZNF449 | c.210G>T p.L70= | Silent (SNP) | VAF 58/98 reads (59%) | called by muse, mutect2, varscan2
- ZSCAN5B | c.537C>A p.A179= | Silent (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824296 C>A | 3'Flank (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3995A>G | RNA (SNP) | VAF 46/247 reads (19%) | called by muse, mutect2, varscan2
- AC068643.2 | n.593+3649T>A | Intron (SNP) | VAF 14/200 reads (7%) | catalogued as rs1046877489; called by muse, mutect2
- AC073648.1 | n.193C>A | RNA (SNP) | VAF 14/85 reads (16%) | catalogued as rs557688591; called by muse, mutect2, varscan2
- ACSM3 | c.1224+60C>A | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ADGRG2 | c.304+36dup | Intron (INS) | VAF 20/49 reads (41%) | called by mutect2, pindel, varscan2
- AL353804.4 | chrX:73823136 A>T | 5'Flank (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- AL590867.2 | n.52C>G | RNA (SNP) | VAF 67/263 reads (25%) | catalogued as rs375853555; called by muse, mutect2, varscan2
- ANAPC1P4 | n.1886A>G | RNA (SNP) | VAF 39/775 reads (5%) | called by muse, mutect2
- ARL13B | c.*98C>A | 3'UTR (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2
- BLK | c.*17G>T | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.-7G>T | 5'UTR (SNP) | VAF 80/168 reads (48%) | called by muse, mutect2, varscan2
- C12orf43 | c.*2410G>T | 3'UTR (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- CACNA1G | c.-354C>T | 5'UTR (SNP) | VAF 13/44 reads (30%) | catalogued as rs907054784; called by muse, mutect2, varscan2
- CBLIF | c.79+100G>C | Intron (SNP) | VAF 48/386 reads (12%) | called by muse, mutect2, varscan2
- COL5A1 | c.654+7471C>G | Intron (SNP) | VAF 34/109 reads (31%) | catalogued as COSV65676009; called by muse, mutect2, varscan2
- CSTF3 | c.458+83C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs893570308; called by muse, mutect2, varscan2
- DCHS2 | n.5194C>G | RNA (SNP) | VAF 49/204 reads (24%) | catalogued as COSV61774147; called by muse, varscan2
- DPY19L2P1 | n.559G>T | RNA (SNP) | VAF 65/273 reads (24%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.328G>A | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as rs765456832; called by muse, mutect2
- FAM172BP | n.975C>G | RNA (SNP) | VAF 72/210 reads (34%) | called by muse, varscan2
- GRIK2 | c.2563-4352C>A | Intron (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- HMG20B | c.*65T>C | 3'UTR (SNP) | VAF 9/26 reads (35%) | catalogued as rs780652392; called by muse, mutect2, varscan2
- HTR3E | c.68-9C>A | Intron (SNP) | VAF 39/784 reads (5%) | catalogued as rs147469576; called by muse, mutect2
- LAMA2 | c.8244+20C>G | Intron (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- LAMTOR5 | c.-19G>T | 5'UTR (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- LILRB1 | chr19:54638705 T>C | 3'Flank (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- LRRC37A6P | n.2385C>T | RNA (SNP) | VAF 56/202 reads (28%) | catalogued as rs768303732; called by muse, mutect2, varscan2
- LTF | c.-30C>G | 5'UTR (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1999-31402del | Intron (DEL) | VAF 15/95 reads (16%) | catalogued as rs1562452440; called by mutect2, pindel, varscan2
- MAP3K19 | c.-22A>T | 5'UTR (SNP) | VAF 87/233 reads (37%) | called by muse, mutect2, varscan2
- MDGA2 | c.1525+1899T>C | Intron (SNP) | VAF 30/112 reads (27%) | called by muse, varscan2
- NEB | c.19582+18G>A | Intron (SNP) | VAF 62/226 reads (27%) | called by muse, mutect2, varscan2
- ODF3B | c.540+18_540+40del | Intron (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- OR4C4P | n.635C>T | RNA (SNP) | VAF 34/273 reads (12%) | catalogued as rs768384569; called by muse, mutect2, varscan2
- PACRGL | c.*56+2754C>A | Intron (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- PLAU | c.58-43A>G | Intron (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- PRKAG3 | c.1168+26C>T | Intron (SNP) | VAF 18/68 reads (26%) | catalogued as rs777434186; called by muse, mutect2, varscan2
- PXYLP1 | c.80-3759C>T | Intron (SNP) | VAF 52/264 reads (20%) | called by muse, varscan2
- RRAS2 | c.-20C>A | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- SCIMP | c.-13T>A | 5'UTR (SNP) | VAF 74/140 reads (53%) | called by muse, mutect2, varscan2
- SLC26A3 | c.-23C>G | 5'UTR (SNP) | VAF 32/330 reads (10%) | called by muse, mutect2
- SLC9A3 | c.*1608C>T | 3'UTR (SNP) | VAF 20/150 reads (13%) | called by muse, varscan2
- SNORD115-19 | n.5C>A | RNA (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- SSPOP | n.15363T>C | RNA (SNP) | VAF 25/145 reads (17%) | called by muse, mutect2, varscan2
- ST6GAL1 | c.706-26G>A | Intron (SNP) | VAF 64/520 reads (12%) | catalogued as rs759687307; called by muse, mutect2, varscan2
- TRHDE | chr12:72272008 C>T | 5'Flank (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- TSC2 | c.600-29G>T | Intron (SNP) | VAF 60/149 reads (40%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23276G>A | Intron (SNP) | VAF 91/254 reads (36%) | catalogued as rs761738753, COSV59381483; called by muse, mutect2, varscan2
- WASHC3 | c.151-4464G>A | Intron (SNP) | VAF 19/149 reads (13%) | catalogued as rs1388513720; called by muse, mutect2, varscan2
- ZEB2 | c.73+5870A>C | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
